EXCEPTIONAL_RESPONDERS case ER-B0C3 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f8e65b00-6fa7-4c0b-8b01-ba059cbc8549

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1954; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Head, face or neck, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: metastasis; Age at diagnosis: 61.1 years (22,315 days); Year of diagnosis: 2015; AJCC staging edition: 7th; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 643 days (1.8 years); Days to best overall response: 393 days (1.1 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin + Fluorouracil; Days to treatment start: 34 days; Days to treatment end: 139 days.
   Treatment given: Therapeutic agents: Cetuximab; Days to treatment start: 34 days.

Follow-up (1 entry)
- Days to follow up: 643 days (1.8 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 24 days; Days progression-free: 643 days (1.8 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0C3-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample ER-B0C3-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0C3-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
